Gene-level copy-number profile of tumor specimen TCGA-B0-4696-01A from TCGA case TCGA-B0-4696, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 58.4 years (21,317 days).
Specimen TCGA-B0-4696-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.9e5b6046-1d2c-44af-8430-421ec0036bb6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B0-4696-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0e579b92-d985-4012-8d4b-ec1c2df7eaaa

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 154; copy number 2: 9,784; copy number 3: 12,787; copy number 4: 21,367; copy number 5: 5,687; copy number 6: 4,564; copy number 7: 4,655; copy number 8: 290; copy number 9: 385; copy number 10: 83; copy number 11: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-B0-4696-01): tumor purity 0.73, ploidy 3.87, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:21,233,168–21,523,783, 5 genes: AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 523 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:17,157,162–18,444,817, 1 gene, copy number 10 (within-gene range 3–10): TBC1D5.
- chr3:17,664,963–19,702,795, 15 genes, copy number 10: RNU7-10P, AC104451.1, AC104451.2, AC104297.1, PDCL3P3, AC132807.1, AC132807.2, SATB1, AC144521.1, SATB1-AS1, RAD23BP1, RNU6-138P, KCNH8, MIR4791, AC061958.1.
- chr5:8,207,019–10,269,918, 53 genes, copy number 9: AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3.
- chr5:25,701,217–27,121,150, 14 genes, copy number 11: RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P.
- chr6:41,789,896–41,895,361, 1 gene, copy number 9 (within-gene range 6–9): USP49.
- chr6:41,832,854–42,050,357, 8 genes, copy number 9 (within-gene range 5–9): AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1.
- chr6:42,564,029–44,553,281, 91 genes, copy number 9 (broad region; genes not listed).
- chr6:49,077,712–49,713,590, 12 genes, copy number 10: AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2.
- chr6:49,721,931–49,744,437, 2 genes, copy number 10: AL121950.1, CRISP3.
- chr11:66,312,853–67,317,431, 54 genes, copy number 9: AP001107.3, CD248, RIN1, AP001107.6, BRMS1, B4GAT1, AP001107.9, SLC29A2, Metazoa_SRP, BRD9P1, RNU1-84P, AP001107.5, NPAS4, AP002748.1, MRPL11, AP002748.3, PELI3, AP002748.4, DPP3, AP002748.5, BBS1, AP002748.6, ZDHHC24, ACTN3, AP002748.2, CTSF, CCDC87, CCS, RNU4-39P, RBM14, RBM14-RBM4, RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86, SYT12, MIR6860, RHOD, KDM2A, AP001885.1, AP001885.3, GRK2, ANKRD13D, SSH3, AP001885.2.
- chr12:459,939–4,276,252, 88 genes, copy number 10–11 (within-gene range 8–11) (broad region; genes not listed).
- chr12:5,032,388–5,383,653, 6 genes, copy number 10 (within-gene range 7–10): AC005906.1, KCNA5, AC005906.3, LINC02443, AC006206.2, AC006206.1.
- chr19:56,189,570–58,605,223, 178 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 154. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
